TCGA case TCGA-VS-A9UR — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Cervix uteri; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/adc60720-ac20-4e73-9c37-3ad3119c07d6

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Brazil; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Mucinous adenocarcinoma, endocervical type (the primary disease): ICD-O-3 morphology code: 8482/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 53.9 years (19,688 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic M: MX; FIGO stage: Stage IIA; FIGO staging edition year: 2009; Tumor grade: GX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 44 days; Days to treatment end: 85 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 45 days; Days to treatment end: 90 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 92 days; Days to treatment end: 127 days; Treatment dose: 2,800 cGy; Treatment outcome: Complete Response; Number of fractions: 4; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 99 days; Days to treatment end: 108 days; Treatment dose: 900 cGy; Treatment outcome: Complete Response; Number of fractions: 5; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2,800 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 6; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Treatment dose: 5,400 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.
2. Metastasis of diagnosis 1 (Mucinous adenocarcinoma, endocervical type), site: Retroperitoneum. Age at diagnosis: 55.8 years (20,363 days); Days to diagnosis: 675 days (1.8 years); Prior treatment: Yes.

Follow-up (6 entries)
- Day 0 (prior to adjuvant therapy): ECOG performance status: 1.
- Days to follow up: 455 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 591 days (1.6 years); ECOG performance status: 1.
- Day 675 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Retroperitoneum; Days to progression: 675 days (1.8 years).
- Days to follow up: 793 days (2.2 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 611.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Pregnant at diagnosis: No.
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 161 cm; BMI: 24.7.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VS-A9UR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 80 mg.
  Slide TCGA-VS-A9UR-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-VS-A9UR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VS-A9UR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 5; Total pregnancy count: 5; Tobacco smoking history indicator: 1; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Mucinous Adenocarcinoma of Endocervical Type; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other).
- Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: 3D conformal.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent fractions total: 6.
- Follow-up form 1: Lost to follow-up: No; Performance status other timing: Follow up; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 793 days; disease-specific survival: no event (censored), 793 days; disease-free interval: event (new tumor event after initially disease-free), 675 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 675 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VS-A9UR-01A-11D-A42N-01): tumor purity 0.8, ploidy 1.84, whole-genome doublings 0.
